Gene-level copy-number profile of tumor specimen TCGA-63-A5MY-01A from TCGA case TCGA-63-A5MY, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-A5MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.98b1f009-ae6a-4677-8099-7854dd17b0d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0319cea3-49ce-42cb-8be8-80a6a3ad3b6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 18,649; copy number 2: 34,074; copy number 3: 4,015; copy number 4: 1,932; copy number 5: 672; copy number 6: 136; copy number 7: 80; copy number 8: 156; copy number 12: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MY-01A-11D-A26L-01): tumor purity 0.85, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr3:63,228,315–64,003,462, 10 genes (within-gene range 0–2): SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1.
- chr4:17,629,306–17,781,621, 1 gene (within-gene range 0–1): FAM184B.
- chr4:186,587,794–186,726,722, 2 genes (within-gene range 0–1): FAT1, AC107050.1.
- chr5:60,021,249–60,304,151, 2 genes: AC034234.1, RNU6-806P.
- chr9:21,077,104–22,455,740, 54 genes: IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr11:18,886,933–18,887,920, 1 gene: MRGPRX6P.
- chr15:56,087,280–56,465,137, 10 genes (within-gene range 0–1): RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,050 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:59,694,762–68,261,230, 174 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr3:195,836,193–198,222,513, 97 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–19,234,487, 353 genes, copy number 5–7 (broad region; genes not listed).
- chr7:105,439,661–106,770,207, 19 genes, copy number 5 (within-gene range 3–5): PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1.
- chr8:35,235,475–35,796,550, 1 gene, copy number 5 (within-gene range 1–5): UNC5D.
- chr8:35,525,176–39,105,445, 84 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr9:26,746,953–27,297,150, 16 genes, copy number 5: AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN.
- chr20:30,278,906–40,758,636, 306 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,268. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
